Somatic mutation profile of tumor specimen TCGA-CN-4728-01A (aliquot TCGA-CN-4728-01A-01D-1434-08) from TCGA case TCGA-CN-4728, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.6 years (20,660 days).
Specimen TCGA-CN-4728-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29d20371-8198-4d9f-be9e-9be80c243808.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4728-10A (Blood Derived Normal), aliquot TCGA-CN-4728-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7561b5c-958c-4e30-b218-11ca4d676da4

The open-access MAF lists 114 somatic variants for this specimen: 84 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 28, Nonsense Mutation 4, Frame Shift Ins 3, 5'Flank 2, Frame Shift Del 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PSG4 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 41/484 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.29); PolyPhen possibly damaging (0.854); catalogued as COSV54932991; called by muse, mutect2
- ABCA7 | c.790+1G>A p.X264_splice | Splice Site (SNP) | VAF 18/212 reads (8%) | catalogued as COSV99565638; called by muse, mutect2
- ACKR1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 105/685 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs1216886104, COSV63674830; called by muse, mutect2, varscan2
- ADCY8 | c.2180C>T p.T727M | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs748382418, COSV53919162; called by muse, mutect2, varscan2
- ADH5 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1300365217, COSV56447996, COSV99596231; called by muse, mutect2, varscan2
- AFF2 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60664320; called by muse, mutect2, varscan2
- AFF3 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1163398397, COSV100418651, COSV100418770; called by muse, mutect2, varscan2
- AHCTF1 | c.1749A>G p.I583M (on ENST00000366508; = p.I557M on NM_015446.5) | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV100403524; called by muse, mutect2
- AKAP13 | c.1631A>T p.D544V | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100773618; called by muse, mutect2, varscan2
- ANKAR | c.3904C>G p.Q1302E | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV99854140; called by muse, mutect2, varscan2
- AVEN | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs926106482, COSV100145459; called by muse, mutect2
- BMPER | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs763448943, COSV99032574, COSV99778978; called by muse, mutect2
- CACHD1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99262077; called by muse, mutect2
- CD163 | c.2744C>G p.A915G | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV100775804; called by muse, mutect2
- CLCN3 | c.1856G>T p.W619L | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100641679; called by muse, mutect2
- CLDN2 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194923745, COSV100390096; called by muse, mutect2, varscan2
- COL11A1 | c.4385G>C p.G1462A | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100614811, COSV100616142; called by muse, mutect2
- CTDNEP1 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as COSV100020983; called by muse, mutect2, varscan2
- CYP4A22 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs141856283, COSV99594800; called by muse, mutect2, varscan2
- DGKG | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.39); catalogued as rs373781204; called by muse, mutect2
- DST | c.1921C>A p.H641N (on ENST00000361203 / NM_001374722.1; = p.H315N on NM_001723.6) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99749119; called by muse, mutect2
- ELMO3 | c.658C>T p.P220S (on ENST00000652269; = p.P167S on NM_024712.5) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV100681561; called by muse, mutect2, varscan2
- EPS8 | c.2268C>A p.F756L | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99843044; called by muse, mutect2, varscan2
- ERV3-1 | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as COSV99275574; called by muse, mutect2, varscan2
- FANCI | c.2223C>G p.I741M | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100167859; called by muse, mutect2
- FASTKD1 | c.1315A>T p.I439F | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV101494289, COSV101494291; called by muse, mutect2, varscan2
- FGFR3 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs949596399; called by muse, mutect2, varscan2
- FLT4 | c.1701G>T p.E567D | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV99986786; called by muse, mutect2, varscan2
- GOLIM4 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 30/308 reads (10%) | catalogued as COSV100462912; called by muse, mutect2
- GRIP2 | c.1039G>A p.E347K (on ENST00000619221; = p.E250K on NM_001080423.4) | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs868127503, COSV99817243; called by muse, mutect2
- HNF4A | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100291322; called by muse, mutect2
- HTRA1 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); catalogued as COSV100934741; called by muse, mutect2, varscan2
- HYOU1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781956168, COSV68217498; called by muse, mutect2
- IFT80 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 27/310 reads (9%) | catalogued as COSV100424653; called by muse, mutect2
- IGSF10 | c.2867C>A p.T956K | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV56781291; called by muse, mutect2, varscan2
- IGSF10 | c.2866A>G p.T956A | Missense Mutation (SNP) | VAF 112/377 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV99179064; called by muse, mutect2, varscan2
- INTS5 | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100399582; called by muse, mutect2
- KALRN | c.2008G>T p.A670S | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV99563695; called by muse, mutect2
- KCNA3 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs769925298, COSV100871243; called by muse, mutect2, varscan2
- KIAA1549 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV54307679; called by muse, mutect2
- KIF14 | c.4219G>T p.A1407S | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100950800; called by muse, mutect2, varscan2
- KIF20B | c.951G>C p.W317C | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99589877; called by muse, mutect2
- L3MBTL1 | c.790G>C p.E264Q (on ENST00000418998 / NM_001377303.1; = p.E174Q on NM_015478.7) | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as COSV100917154; called by muse, mutect2
- LRP2 | c.9348C>A p.D3116E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs754311160, COSV99787989; called by muse, mutect2, varscan2
- MPND | c.358A>T p.T120S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99515141; called by muse, mutect2
- NES | c.3317G>T p.G1106V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100957848; called by muse, mutect2, varscan2
- OR2M7 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV100522518; called by muse, mutect2, varscan2
- OR5P2 | c.680C>A p.T227N | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as COSV61490241; called by muse, mutect2
- OR5R1 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100393397; called by muse, mutect2, varscan2
- OR6C70 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100524297, COSV100524398; called by muse, mutect2, varscan2
- OR8G1 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 15/195 reads (8%) | catalogued as COSV100422385; called by muse, mutect2
- PREX2 | c.3140T>G p.I1047R | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99905474, COSV99906672; called by muse, mutect2, varscan2
- PTCH1 | c.3875C>T p.S1292F | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs760216958, COSV100108282; called by muse, mutect2
- PTPN9 | c.373C>G p.H125D | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV100144263; called by muse, mutect2
- PTRH2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99292103; called by muse, mutect2, varscan2
- RASIP1 | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99710691; called by muse, mutect2
- RPS19 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as CD167145, CM993208, COSV99702621; called by muse, mutect2, varscan2
- RSPH4A | c.1512G>C p.Q504H | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV99994095; called by muse, mutect2
- SASH1 | c.2882A>G p.H961R | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV100821151; called by muse, mutect2
- SCN9A | c.5640C>G p.I1880M (on ENST00000303354; = p.I1869M on NM_002977.3) | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100312493; called by muse, mutect2, varscan2
- SPCS3 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV101543696; called by muse, mutect2, varscan2
- SSRP1 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs867945111, COSV99554876; called by muse, mutect2
- SUPT5H | c.2451G>C p.Q817H | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.036); catalogued as COSV100782045; called by muse, mutect2, varscan2
- SUZ12 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100496849; called by muse, mutect2
- THRB | c.756A>C p.Q252H | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99769413; called by muse, mutect2
- TIMELESS | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.061); catalogued as COSV57512745; called by muse, mutect2
- TIMELESS | c.2815G>T p.E939* | Nonsense Mutation (SNP) | VAF 13/265 reads (5%) | catalogued as COSV99973884; called by muse, mutect2
- TOR3A | c.1097T>C p.I366T | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs761072022, COSV100751288; called by muse, mutect2
- TP53 | c.173del p.P58Qfs*65 | Frame Shift Del (DEL) | VAF 95/362 reads (26%) | catalogued as COSV52675650, COSV53041942, COSV53097051; called by mutect2, pindel, varscan2
- TSNAXIP1 | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 52/626 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV101183904; called by muse, mutect2
- UMOD | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100208246, COSV56777291; called by muse, mutect2
- WDFY1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs550293700, COSV99239380; called by muse, mutect2
- WDR53 | c.791A>G p.K264R | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV100218059; called by muse, mutect2
- ZC3H4 | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 69/432 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs755009721, COSV99452177; called by muse, mutect2, varscan2
- ZNF329 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100798716, COSV63773308; called by muse, mutect2
- ZNF473 | c.1841C>G p.S614C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV99568761; called by muse, mutect2
- ZNF574 | c.1106G>T p.C369F | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55903030, COSV99726018; called by muse, mutect2
- ZNF771 | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100075221; called by muse, mutect2
- ZSCAN22 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as COSV100308331; called by muse, mutect2
- CYB561 | c.649del p.Y217Tfs*3 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- PPP2R1A | c.1437dup p.A480Cfs*31 | Frame Shift Ins (INS) | VAF 23/176 reads (13%) | called by mutect2, pindel, varscan2
- SOX21 | c.169_183del p.F57_A61del | In Frame Del (DEL) | VAF 30/140 reads (21%) | called by mutect2, pindel, varscan2
- TFAP2C | c.718dup p.Y240Lfs*7 | Frame Shift Ins (INS) | VAF 19/134 reads (14%) | called by mutect2, pindel, varscan2
- TTC17 | c.501dup p.Y168Ifs*2 | Frame Shift Ins (INS) | VAF 28/152 reads (18%) | called by mutect2, pindel, varscan2
- ADCY3 | c.1323A>T p.V441= | Silent (SNP) | VAF 28/194 reads (14%) | catalogued as COSV99568117; called by muse, mutect2, varscan2
- ANGEL1 | c.1560C>T p.I520= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as rs1470133203, COSV51875112; called by muse, mutect2
- ARHGAP44 | c.234G>C p.L78= | Silent (SNP) | VAF 24/431 reads (6%) | catalogued as COSV99310561; called by muse, mutect2
- CAMSAP1 | c.1869C>T p.I623= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as rs765610866, COSV100409786; called by muse, mutect2
- CNGA3 | c.933C>T p.L311= | Silent (SNP) | VAF 19/224 reads (8%) | catalogued as COSV99736600; called by muse, mutect2
- CYP7A1 | c.561C>T p.I187= | Silent (SNP) | VAF 28/252 reads (11%) | catalogued as COSV100052325; called by muse, mutect2, varscan2
- DNAJB6 | c.300C>T p.F100= | Silent (SNP) | VAF 21/302 reads (7%) | catalogued as COSV100055545; called by muse, mutect2
- ERCC2 | c.1272A>G p.R424= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV101228723; called by muse, mutect2, varscan2
- ISLR2 | c.1956C>T p.L652= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV100679518; called by muse, mutect2
- MKKS | c.192C>G p.L64= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV100726276; called by muse, mutect2
- MYH15 | c.3664C>T p.L1222= | Silent (SNP) | VAF 16/238 reads (7%) | catalogued as COSV99843047; called by muse, mutect2
- NME6 | c.237G>A p.G79= (on ENST00000415053; = p.G87= on NM_005793.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100189366; called by muse, mutect2
- P2RY10 | c.984C>T p.L328= | Silent (SNP) | VAF 22/177 reads (12%) | catalogued as COSV50681027; called by muse, mutect2, varscan2
- PDE4B | c.1614T>C p.V538= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100303252; called by muse, mutect2, varscan2
- PIKFYVE | c.243G>T p.S81= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100010509; called by muse, mutect2
- PIP4K2C | c.585C>T p.N195= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as rs147041101, COSV61605836; called by muse, mutect2
- PSMD2 | c.1692C>G p.L564= | Silent (SNP) | VAF 6/149 reads (4%) | catalogued as COSV100031696; called by muse, mutect2
- RNF139 | c.1041G>A p.E347= | Silent (SNP) | VAF 53/421 reads (13%) | catalogued as rs750271436, COSV99413339; called by muse, mutect2, varscan2
- SETDB2 | c.954C>T p.S318= | Silent (SNP) | VAF 23/315 reads (7%) | catalogued as COSV99320696; called by muse, mutect2
- SLC25A5 | c.654G>A p.Q218= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100510300; called by muse, mutect2, varscan2
- SPON1 | c.1857A>T p.P619= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV100115687; called by muse, mutect2, varscan2
- SYNE1 | c.24768T>C p.N8256= (on ENST00000367255 / NM_182961.4; = p.N8185= on NM_033071.3) | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as COSV99561540; called by muse, mutect2
- TMTC2 | c.318C>A p.S106= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV100337823; called by muse, mutect2
- VIL1 | c.2460C>G p.L820= | Silent (SNP) | VAF 34/287 reads (12%) | catalogued as COSV99294335; called by muse, mutect2, varscan2
- VWA3B | c.2388C>T p.L796= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as rs1471294650, COSV101346013; called by muse, mutect2
- ZC3H12A | c.1716G>C p.V572= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100897696; called by muse, mutect2
- ZNF606 | c.2124C>T p.Y708= | Silent (SNP) | VAF 24/179 reads (13%) | catalogued as COSV100071747; called by muse, mutect2, varscan2
- ZNF660 | c.183G>A p.Q61= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100502717, COSV59550145; called by muse, mutect2
- AP000769.5 | chr11:65499321 C>A | 5'Flank (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- S1PR3 | chr9:88991077 C>G | 5'Flank (SNP) | VAF 7/62 reads (11%) | catalogued as rs1352808859, COSV100560853, COSV57836549; called by muse, varscan2
